Gene-level copy-number profile of tumor specimen MP2PRT-PAPISW-TMP1-A from MP2PRT case MP2PRT-PAPISW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,634 days).
Specimen MP2PRT-PAPISW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f86c047b-697b-47bc-a5fd-3bd4eb3e98fe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPISW-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/46d48399-5418-4879-a6b5-e78b8cac8a88

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 47; copy number 2: 39,078; copy number 3: 213; copy number 4: 3,008; copy number 5: 15,822; copy number 7: 720; copy number 12: 10.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–5): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16,552 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,938,744–216,423,448, 1,709 genes, copy number 5 (broad region; genes not listed).
- chr4:49,096–49,246,915, 706 genes, copy number 5 (broad region; genes not listed).
- chr4:51,843,000–68,497,604, 219 genes, copy number 5 (broad region; genes not listed).
- chr4:68,704,600–190,092,279, 1,625 genes, copy number 5 (broad region; genes not listed).
- chr6:391,752–26,139,116, 428 genes, copy number 5 (broad region; genes not listed).
- chr6:26,269,405–170,738,536, 2,502 genes, copy number 5 (broad region; genes not listed).
- chr10:14,061–133,778,699, 2,261 genes, copy number 5 (broad region; genes not listed).
- chr14:19,954,490–22,423,042, 180 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr14:22,455,249–106,879,812, 1,973 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr17:142,789–83,240,804, 3,020 genes, copy number 5–12 (broad region; genes not listed).
- chr18:45,034–80,247,514, 1,199 genes, copy number 5 (broad region; genes not listed).
- chr21:10,413,477–46,691,226, 730 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
